TCGA case TCGA-FI-A2D5 — Uterine Corpus Endometrial Carcinoma (TCGA-UCEC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Corpus uteri; Tissue source site: Washington University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/dcfbe781-a92a-45b5-b80a-e3bb3bdc0d9a

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 56 years; Vital status: Dead; Days to death: 421 days (1.2 years).

Diagnoses (3)
1. Endometrioid adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8380/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Endometrium; Classification of tumor: primary; Age at diagnosis: 56.6 years (20,666 days); Year of diagnosis: 2009; Method of diagnosis: Dilation and Curettage Procedure; FIGO stage: Stage IVB; FIGO staging edition year: 2009; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: Yes; Prior treatment: No; Residual disease: R0.
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes positive: 1; Lymph nodes tested: 2.
   Pathology details: Lymph node involved site: Aortic; Lymph nodes tested: 0.
   Pathology details: Consistent pathology review: Yes; Percent tumor invasion: 100.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Days to treatment start: 133 days; Days to treatment end: 245 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Progressive Disease; Days to treatment start: 283 days; Days to treatment end: 363 days; Treatment dose: 60 cGy; Course number: 1; Number of fractions: 30; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Surgery, Open; Initial disease status: Initial Diagnosis.
   Recorded as not given: Pharmaceutical Therapy, NOS (Tamoxifen), prior to diagnosis.
2. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Classification of tumor: Synchronous primary.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Metastasis of diagnosis 1 (Endometrioid adenocarcinoma, NOS), site: Vagina, NOS. Age at diagnosis: 57.3 years (20,946 days); Days to diagnosis: 280 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Surgery, NOS, for progressive disease.

Follow-up (3 entries)
- Day 280 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Vagina, NOS; Days to progression: 280 days.
- Days to follow up: 421 days (1.2 years); Disease response: With Tumor.
- Peritoneal washing results: Positive; Timepoint: Initial Diagnosis.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Never Used; Hormonal replacement therapy status: No; Menopause status: Postmenopausal; Number of pregnancies: 1; Pregnancy outcome: Full Term Birth, NOS.
- Timepoint category: Initial Diagnosis; Weight: 92 kg; Height: 160 cm; BMI: 35.9.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-FI-A2D5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 60 mg.
  Slide TCGA-FI-A2D5-01A-01-TSA: Section location: Top; Percent tumor cells: 83; Percent tumor nuclei: 98; Percent normal cells: 0; Percent necrosis: 15; Percent stromal cells: 2; Percent lymphocyte infiltration: 15; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 3.
- Sample TCGA-FI-A2D5-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-FI-A2D5-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: With tumor; Submitted tumor site: Endometrial; Histologic diagnosis: Endometrioid endometrial adenocarcinoma; Surgical approach at diagnosis: open.
- Follow-up form: History menopausal hormone therapy: No, I have never taken menopausal hormone therapy; Hypertension diagnosis: No; Diabetes diagnosis indicator: No; Pregnancies full term count: 1; History colorectal cancer: No; Tumor status: With tumor; Treatment outcome first course: Partial Remission/Response; New tumor event site other: vaginal cuff; New tumor event type: Metastatic; New tumor event surgery: No; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes.
- Drug treatment 1: Pharmaceutical therapy drug name: Carboplatinum; Treatment best response: Clinical Progressive Disease.
- Radiation treatment: Therapy regimen: Progression.
- Other malignancy form: Malignancy type: Synchronous Malignancy; Other malignancy anatomic site: Lung; Other malignancy histological type: Lung Adenocarcinoma- Not Otherwise Specified (NOS).
- Other malignancy form, Radiation treatment: History radiation treatment to site of TCGA tumor: No.

GDC annotations on this case (curator notes; quoted as recorded):
- Synchronous malignancy: Patient had synchronous lung adenocarcinoma, NOS. No systemic radiation or chemotherapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 421 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 421 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 280 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-FI-A2D5-01A-11D-A17C-01): tumor purity 0.6, ploidy 2, whole-genome doublings 0.
